Surgical pathology report (de-identified scan), TCGA case TCGA-44-A47G, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-A47G-01A (Primary Tumor).

[page 1 of 2]
1CD03

Adenocarcinoma, NOS
8140/3

Revised Surgical Pathology Report

Site: lung, upper lobe

Procedure:

Reason for revision: Removal of voice recognition error in the diagnosis.

9-5-12
RD

G34.1

Diagnosis

- A. Lung, posterior apical segment right upper lobe, resection:
Scattered clusters of atypical cells compatible with moderately differentiated adenocarcinoma. Emphysema and subpleural elastosis.
- B. Lymph node, level XI, biopsy: A single lymph node is negative for malignancy.
- C. Lymph node, level VII, biopsy: A single lymph node is negative for malignancy
- D. Lymph node, level X, biopsy: A single lymph node is negative for malignancy
- E. Lung, right upper lobe, resection: Moderately differentiated adenocarcinoma
- F. 2R fat, biopsy: There is no evidence of malignancy in either of 2 lymph nodes

Microscopic Description:

E
Histologic type: Adenocarcinoma
Histologic grade: 2
Tumor size: 1 cm
Bronchial resection margin: Negative for malignancy
Pulmonary margin of resection: Negative for malignancy
Pleura: Negative for malignancy
Vascular invasion: Absent
Attached lymph nodes: There is no evidence of malignancy in any of 3 peribronchial lymph nodes.
pTNM stage: T1 (parts of the tumor were in specimens A and E, so the size of the tumor is difficult to determine).
Non-tumorous lung: Emphysema and subpleural elastosis. Arteriolar medial hypertrophy.

Specimen

- A. Lung, posterior apical segment right upper lobe
B. Level XI
C. Level VII
D. Level X node
E. Right upper lobe
F. 2R fat

Intraoperative Consultation

- A. Posterior apical segment right upper lobe, wedge biopsy: Non small cell carcinoma at stapled margin.

[page 2 of 2]
Gross Description

A. Received fresh for frozen section labeled "A. right posterior apical segment right upper lobe" is a 7 x 2.5 I2 0.0 cm wedge biopsy of lung with 8 cm stapled resection margin. The pleura appears red smooth and unremarkable. A vaguely palpable nodule is present in the center of the specimen. The stapled resection margins are removed the pulmonary parenchyma deep to the stapled margin is inked black. The specimen is sectioned to reveal a red spongy cut surface without a definitive mass. A representative sections are frozen as frozen section AFS 1 and 2. The remainder of the tissue except for the stapled margin is entirely submitted for permanent sections AS- 10

Specimen B. is received unfixed labeled level XI and consists of a piece of black soft tissue measuring 0.2 cm in greatest dimension. AS-1

Specimen C. is received unfixed labeled level VII and consists of a piece of black soft tissue measuring 0.4 cm in greatest dimension. AS-1

Specimen D. is received unfixed labeled level X node and consists of a piece of red and black soft tissue measuring 1 cm in greatest dimension. AS-1

Specimen E. is received unfixed in the right upper lobe and consists of a red and black lung lobe measuring 14 by 11 point by 4 cm. Received is additional small irregular piece of stapled lung tissue measuring 2.5 x 1.5 x 0.6 7 cm. 1 lobe is sectioned at 1 cm intervals. There is a relatively central defect in the pleural surface that may represent the site of the previous biopsy. There is a small tan-white areas of subpleural an adjacent to the defect that is compatible with tumor and measures 1 cm diameter. A portion of tumor is taken for research purposes. Sections after fixation.

Block summary: 1 bronchial/vascular margins; 2,3 pulmonary margins; 4-6 tumor; 7,8 normal lung.

Specimen F. is received unfixed labeled "2R fat pad" and consists of multiple pieces of yellow and red soft tissue occupying approximately one mL in volume. AS-1

0

8/25/12

Source: NCI Genomic Data Commons file ee49cdfe-b845-4464-80de-ae6b817b55cd (TCGA-44-A47G.103CEC27-11AE-4E7F-88F4-530A94CB5278.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).